Somatic mutation profile of tumor specimen C3N-01849-04 (aliquot CPT0224780006) from CPTAC case C3N-01849, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.3 years (22,737 days).
Specimen C3N-01849-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a87451d1-ef0a-4450-b709-ce51048c28c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01849-31 (Blood Derived Normal), aliquot CPT0224830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc46e663-4b82-4b9a-9563-82597b014bca

The open-access MAF lists 40 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 7, Intron 4, 5'Flank 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 164/212 reads (77%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121909241, CM045431, CM063078, CM074468, COSV64288421, COSV64288528, COSV64293854; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- PYGM | c.1239+1G>A p.X413_splice | Splice Site (SNP) | VAF 120/285 reads (42%) | catalogued as rs759657964, CS063377; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAN | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1488779040; called by muse, mutect2, varscan2
- AGER | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs373730068; called by muse, mutect2, varscan2
- BPIFB4 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs375384271; called by muse, mutect2, varscan2
- CACNG6 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs773485518, COSV53168144; called by muse, mutect2, varscan2
- CPAMD8 | c.1280C>T p.T427M (on ENST00000651564; = p.T380M on NM_015692.5) | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as rs183563770, COSV52237911; called by muse, mutect2, varscan2
- GNRH1 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99373722; called by muse, mutect2, varscan2
- HDAC11 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 132/372 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs761232237; called by muse, mutect2, varscan2
- KCNB2 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV73049213; called by muse, mutect2, varscan2
- MRGPRX1 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); catalogued as COSV57106460; called by muse, mutect2, varscan2
- MYLK | c.2816C>G p.S939C | Missense Mutation (SNP) | VAF 95/214 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.353); catalogued as COSV100659428; called by muse, mutect2, varscan2
- NF1 | c.3496G>A p.G1166S | Missense Mutation (SNP) | VAF 98/150 reads (65%) | SIFT tolerated (0.5); PolyPhen benign (0.05); catalogued as CS147221, COSV62227948; called by muse, mutect2, varscan2
- NTSR1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.491); catalogued as rs201502964; called by muse, mutect2, varscan2
- PLCL1 | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 72/207 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559099836, COSV70821454, COSV70821834; called by muse, mutect2, varscan2
- UGT2A3 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99280280; called by muse, mutect2, varscan2
- ZNF486 | c.1181A>G p.H394R | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as rs782807429; called by muse, mutect2
- AKT1S1 | c.556G>A p.V186M (on ENST00000344175 / NM_001098633.4; = p.V206M on NM_032375.5) | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDK6 | c.886T>A p.S296T | Missense Mutation (SNP) | VAF 95/342 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GABRB3 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 107/281 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXA2 | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 10/322 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.284); called by muse, mutect2
- KRTAP17-1 | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 89/235 reads (38%) | PolyPhen benign (0.024); called by muse, mutect2
- RPL37A | c.118T>G p.S40A | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SHCBP1L | c.956A>G p.E319G | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TFAP4 | c.527del p.V176Gfs*15 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- TRPS1 | c.1090G>T p.A364S (on ENST00000220888 / NM_001330599.2; = p.A377S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF99 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCDC81 | c.1209G>A p.P403= (on ENST00000445632 / NM_001156474.2; = p.P313= on NM_021827.4) | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs553491893; called by muse, mutect2, varscan2
- CHEK2 | c.1353G>A p.V451= (on ENST00000382580 / NM_001005735.2; = p.V408= on NM_007194.4) | Silent (SNP) | VAF 70/214 reads (33%) | catalogued as COSV100101808; called by muse, mutect2, varscan2
- E2F7 | c.2217G>A p.P739= | Silent (SNP) | VAF 78/222 reads (35%) | catalogued as rs376673165; called by muse, mutect2, varscan2
- EIF4G1 | c.1287A>C p.T429= (on ENST00000346169 / NM_198241.3; = p.T233= on NM_004953.5) | Silent (SNP) | VAF 66/149 reads (44%) | called by muse, mutect2, varscan2
- FBXO41 | c.1588C>A p.R530= | Silent (SNP) | VAF 106/265 reads (40%) | called by muse, mutect2, varscan2
- KIF2A | c.138T>C p.N46= | Silent (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- NXT2 | c.129G>A p.K43= (on ENST00000372106 / NM_001242617.2; = p.K98= on NM_018698.5) | Silent (SNP) | VAF 28/39 reads (72%) | called by muse, mutect2, varscan2
- ALDH3A1 | c.394+199C>A | Intron (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- KCTD2 | chr17:75047203 G>A | 5'Flank (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- MASP1 | c.1090+2908T>G | Intron (SNP) | VAF 126/340 reads (37%) | called by muse, mutect2, varscan2
- PHKB | c.3145-34G>T | Intron (SNP) | VAF 139/171 reads (81%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159434 C>A | 5'Flank (SNP) | VAF 46/56 reads (82%) | called by muse, varscan2
- TSEN54 | c.286-32C>T | Intron (SNP) | VAF 263/504 reads (52%) | catalogued as rs756218128; called by muse, mutect2, varscan2
